Somatic mutation profile of tumor specimen 0DBW4B from CCDI case PBBLPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 2.9 years (1,053 days).
Specimen 0DBW4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 906e471e-4eee-49a9-8019-4625a9063508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBW3X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7bffc5c-f645-4935-8ed5-b8957bafc9ca

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Splice Site 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2683-1G>T p.X895_splice | Splice Site (SNP) | VAF 218/610 reads (36%) | catalogued as COSV55942950; called by muse, varscan2
- CTNND1 | c.2083C>T p.R695C (on ENST00000399050 / NM_001085458.2; = p.R689C on NM_001331.3) | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1332305542, COSV62382394; called by muse, mutect2, varscan2
- DBP | c.775T>A p.W259R | Missense Mutation (SNP) | VAF 102/436 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1360021676; called by muse, mutect2, varscan2
- HOMER3 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs775391920; called by muse, mutect2, varscan2
- MICAL3 | c.4606G>T p.D1536Y | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101490915; called by muse, mutect2, varscan2
- TMTC3 | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 243/911 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99898293; called by muse, mutect2, varscan2
- TRIM8 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200444633; called by muse, mutect2, varscan2
- HMCN1 | c.14758+3_14758+6del p.X4920_splice | Splice Site (DEL) | VAF 72/296 reads (24%) | called by mutect2, varscan2
- LCE1C | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 181/456 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PIGK | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 132/243 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TSC1 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 188/563 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ATG2B | c.5649G>A p.Q1883= | Silent (SNP) | VAF 67/1356 reads (5%) | called by muse, mutect2
- PGLYRP3 | c.621C>A p.I207= | Silent (SNP) | VAF 105/557 reads (19%) | called by muse, mutect2, varscan2
- RFT1 | c.1479G>A p.Q493= | Silent (SNP) | VAF 139/391 reads (36%) | catalogued as rs780448463; called by muse, mutect2, varscan2
- CCDC88A | c.5552-62T>G | Intron (SNP) | VAF 15/435 reads (3%) | called by muse, mutect2
- TNFRSF25 | c.*95A>G | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, varscan2
